Somatic mutation profile of tumor specimen C3N-00168-01 (aliquot CPT0019980009) from CPTAC case C3N-00168, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.5 years (17,349 days).
Specimen C3N-00168-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0142077-7a6d-499b-b5be-9e126ce7b5fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00168-31 (Blood Derived Normal), aliquot CPT0020920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9ba01ee-2e92-49b9-8ebb-59baf052bbe1

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Nonsense Mutation 2, Intron 2, 3'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADTRP | c.197T>A p.V66E | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57643443; called by muse, mutect2
- CAPRIN1 | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1419145733; called by muse, mutect2
- CDHR5 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748626313; called by muse, mutect2, varscan2
- EPHX2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867470047; called by muse, mutect2, varscan2
- GLI2 | c.1970C>A p.A657D (on ENST00000361492 / NM_001374353.1; = p.A674D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs773562626; called by muse, mutect2, varscan2
- KDM3B | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287032605, COSV58692920; called by muse, mutect2
- KRT32 | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56785340; called by muse, mutect2, varscan2
- PDPN | c.329C>T p.T110M (on ENST00000621990; = p.T186M on NM_006474.4) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs368396279; called by muse, mutect2
- PRDM14 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs889482883; called by muse, mutect2
- RNF133 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | catalogued as rs1224943125; called by muse, mutect2, varscan2
- VHL | c.408dup p.V137Cfs*7 | Frame Shift Ins (INS) | VAF 44/347 reads (13%) | catalogued as COSV56544783, COSV56547644; called by mutect2, pindel, varscan2
- ACTB | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- CHUK | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CPNE3 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2
- CPNE3 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- CUBN | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 48/550 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHFR2 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- HIVEP2 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- HOOK3 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- IL21 | c.360+1G>C p.X120_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- ITGA2 | c.2726G>C p.S909T | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- ITPR2 | c.4588A>C p.K1530Q | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- JAG2 | c.3115A>C p.S1039R | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC17 | c.11918C>A p.T3973K | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- NEGR1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2
- OR51I2 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- OVCH1 | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- P3H3 | c.1850A>G p.D617G | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- RRP9 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SEPTIN5 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2
- SPNS1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- YWHAQ | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.53); called by muse, mutect2
- ZNF407 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ZNF91 | c.2548G>T p.G850* | Nonsense Mutation (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- AHSG | c.534C>T p.S178= | Silent (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- COL26A1 | c.318C>T p.S106= (on ENST00000313669 / NM_001278563.3; = p.S104= on NM_133457.4) | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV58128590; called by muse, mutect2
- DOCK6 | c.252G>A p.E84= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- NAV2 | c.2430G>A p.Q810= (on ENST00000396087 / NM_001244963.2; = p.Q787= on NM_145117.5) | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV62337380; called by muse, mutect2
- PTPRT | c.1620G>T p.G540= | Silent (SNP) | VAF 28/336 reads (8%) | catalogued as COSV61961508; called by muse, mutect2
- RALYL | c.144A>C p.I48= | Silent (SNP) | VAF 22/189 reads (12%) | called by muse, mutect2, varscan2
- SLC12A5 | c.507G>A p.T169= (on ENST00000454036 / NM_001134771.2; = p.T146= on NM_020708.5) | Silent (SNP) | VAF 19/170 reads (11%) | catalogued as rs1345353699; called by muse, mutect2, varscan2
- SORBS2 | c.846G>T p.V282= (on ENST00000284776 / NM_021069.5; = p.V375= on NM_003603.6) | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- ZFAND3 | c.441T>C p.S147= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- AL669831.6 | chr1:786117 C>T | 3'Flank (SNP) | VAF 16/146 reads (11%) | called by muse, varscan2
- NALCN | c.2118+16del | Intron (DEL) | VAF 20/153 reads (13%) | called by mutect2, pindel, varscan2
- NDUFC2-KCTD14 | c.311-21440C>T | Intron (SNP) | VAF 22/248 reads (9%) | catalogued as rs1440788637; called by muse, mutect2
